Somatic mutation profile of tumor specimen TARGET-20-PANTWV-04A (aliquot TARGET-20-PANTWV-04A-01D) from TARGET case TARGET-20-PANTWV, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.3 years (5,230 days).
Specimen TARGET-20-PANTWV-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3505b835-21c7-4287-a4fe-0a2c32675d9e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANTWV-14A (Bone Marrow Normal), aliquot TARGET-20-PANTWV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9a70e6c-b922-4aaf-8335-c3d99cc3d420

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 87/311 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PCDHA7 | c.1940T>C p.L647P | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs1408397134; called by muse, mutect2
- PRRC2A | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs1387136296; called by muse, mutect2
- RUSC1 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs747363737; called by muse, mutect2, varscan2
- SEMA4B | c.1387G>A p.V463I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs1161316262; called by muse, mutect2
- TAF6 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.938); catalogued as rs1221508672; called by muse, mutect2
- GAB1 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 48/395 reads (12%) | called by muse, mutect2, varscan2
- IWS1 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.227); called by muse, mutect2
- NRG1 | c.1891G>A p.V631I (on ENST00000405005 / NM_013964.5; = p.V636I on NM_013956.5) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SEC24B | c.1166-1G>A p.X389_splice | Splice Site (SNP) | VAF 139/495 reads (28%) | called by muse, mutect2, varscan2
- TRPM7 | c.5309G>A p.G1770D | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EIF5B | c.3546T>C p.L1182= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as rs1412682971; called by muse, mutect2, varscan2
- PLEKHD1 | c.633G>A p.E211= | Silent (SNP) | VAF 121/373 reads (32%) | called by muse, mutect2, varscan2
- SLC9A5 | c.219G>T p.L73= | Silent (SNP) | VAF 33/136 reads (24%) | called by muse, mutect2, varscan2
